FM case AD10180 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Vulva.
https://portal.gdc.cancer.gov/cases/9ab695cc-a8e0-4a9b-95c4-1d0c98c3f597

Female, 50.8 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the vulva; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
